EXCEPTIONAL_RESPONDERS case ER-ABO1 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/98fc0736-b116-45f2-ab2e-6e62757898e8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1981; Vital status: Alive.

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Age at diagnosis: 27.3 years (9,955 days); Year of diagnosis: 2009; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Days to last follow up: 2,224 days (6.1 years); Days to best overall response: 292 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 250 days; Days to treatment end: 1,489 days (4.1 years).

Follow-up (1 entry)
- Days to follow up: 2,224 days (6.1 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 243 days; Days progression-free: 2,224 days (6.1 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABO1-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT.
  Slide ER-ABO1-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample ER-ABO1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
  Slide ER-ABO1-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
